Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7Z6, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7Z6-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Not provided. MRI: A large region of masslike heterogeneous T2 hyperintensity centered within the right frontal lobe, extending into the genu and anterior body of the corpus callosum. The region of T2 hyperintensity measures approximately 9.3 x 7.3 cm, greatest orthogonal axial dimensions, not significantly changed from prior. Multiple small central T1 hypointense foci, without signal on FLAIR images, likely represent small areas of cystic change/necrosis. No significant enhancement is present in this region. No distant foci of abnormal parenchymal signal are present. Mass effect continues to result in approximately 1.2 cm of right-to-left midline shift, unchanged. No abnormal extra-axial fluid collections. Basal cisterns are patent. The right frontal horn is completely effaced, with partial effacement of the right lateral ventricle body.

GROSS EXAMINATION:

A. "Brain tissue right frontal (AF1-2)", received fresh for frozen section and placed in formalin at [REDACTED] is a 125 gram (postfixation) (7 X 7.3 X 5.6 cm) segment of brain. Approximately 40% of the specimen has an effaced gray-white matter with petechial hemorrhage. The uninvolved brain has a well-defined cerebral cortex with identifiable gyri and well-demarcated gray-white matter. A portion of the specimen was frozen as representative AF1-2 and the frozen section controls are submitted in A1-2, respectively. Additional sections are submitted in A3-8.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue-right frontal": AF1- (rep)- glioma (Dr. [REDACTED])
AF2- (rep)- glioma (Dr. [REDACTED])

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a well-differentiated glial astrocytic characterized by mild hypercellularity and cellular pleomorphism. There are many microcysts. Endothelial proliferation and necrosis are not seen.

IMMUNOHISTOCHEMICAL FINDINGS:

Immunohistochemical stains are performed. The tumor cells are immunopositive for GFAP. HAM-56 highlights endothelial cells. The Ki-67 index is low, approximately 1%-2%.

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the

Some of them may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

DIAGNOSIS:

A. "BRAIN TISSUE, RIGHT FRONTAL" (CRANIOTOMY):

DIFFUSE ASTROCYTOMA (WHO GRADE II).

I certify that I personally conducted the diagnostic evaluation of the above

ICD-O-3

Astrocytoma, grade II 9400/3
Site: Brain, supratentorial NOS C71.0
path @ Brain, frontal lobe C71.1
W 5/5/14

[page 2 of 4]
~~specimen(s) and have rendered the above diagnosis(es).~~

M.D.

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (48% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (42% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - INTACT (NO LOSS)

PTEN - INTACT (NO LOSS)

1p36 - INTACT (NO LOSS)

1p32 - INTACT (NO LOSS)

19q13 - INTACT (NO LOSS)

9p21 - INTACT (NO LOSS)

CHROMOSOME 9 CENTROMERE - INTACT (NO LOSS)

2 OF 4 ABNORMAL MARKERS.

COMMENT: THIS FISH PATTERN CAN BE SEEN IN LOW GRADE GLIOMAS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

, M.D.

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING DIFFUSE ASTROCYTOMA (WHO GRADE II; [REDACTED] BLOCK A4).

LEUCOCYTE COMMON ANTIGEN (LCA): 10% OF POSITIVE CELLS.

MGMT - POSITIVE (20% OF TUMOR CELLS)

EGFR wt - POSITIVE (2+ IN 80% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 50% OF TUMOR CELLS)

AKT - POSITIVE (2+ IN 25% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 50% OF TUMOR CELLS)

CARBONIC ANHYDRASE IX: (0%) NEGATIVE FOR EXPRESSION OF CARBONIC ANHYDRASE IX.

VEGF IMMUNOHISTOCHEMISTRY: POSITIVE (2 x 60% = score 120). Intensity x distribution => 20 is positive.

PDGFR-A IMMUNOHISTOCHEMISTRY: WIDESPREAD (90%) FOR CYTOPLASMIC AND/OR

[page 3 of 4]
MEMBRANE REACTIVITY.

PDGFR-B IMMUNOHISTOCHEMISTRY: WIDESPREAD (80%) FOR CYTOPLASMIC AND/OR
MEMBRANE REACTIVITY.

VEGFR2(KDR) IMMUNOHISTOCHEMISTRY: POSITIVE (2 x 70% = score 140). Intensity x
distribution => 20 is positive.

Please see Image Cytometry Report for results of supplementary
tests.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from
[REDACTED] is a copy of an MGMT Promoter Methylation Assay, obtained at the request
of Dr. [REDACTED] on paraffin block [REDACTED].
The complete report from [REDACTED] is on file in the

Result:

MGMT PROMOTER METHYLATION IDENTIFIED (METHYLATION INDEX = 13.28; SEE NOTE).

Note:

The specimen is considered negative for MGMT promoter methylation when
Methylation Index (MI) is less than 4. MI between 4 and 16 is considered as
low level methylation and should be interpreted with caution since the
significance of low level methylation in gliomas is not well understood. MI
greater than 16 is considered as methylated.

Background:

MGMT (O(6)-methylguanine-DNA methyltransferase) is a DNA repair enzyme
that is involved in the repair of damage caused by a variety of DNA
crosslinking compounds, including alkylating agents. Increased
methylation of the MGMT gene promoter region causes diminished or
silenced expression of the gene, making cells more sensitive to DNA
damage. This relationship has been shown for glioblastomas and
alkylating agents such as Temodar(R) (temozolomide).
Approximately 40% to 45% of glioblastoma multiforme (GBM) tumors
exhibit MGMT gene methylation. Retrospective studies have shown that
detection of MGMT promoter methylation in tumor samples is associated
with an increased likelihood of a favorable response to temozolomide.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE)
specimen. Molecular analysis of the MGMT gene is performed by
methylation-specific PCR. Molecular-based testing is highly accurate but
as in any laboratory test, rare diagnostic errors may occur.

Results of this test are for Investigational Purposes Only. The
performance characteristic of this assay have been determined by
The result should not be used as a diagnostic procedure
without confirmation of the diagnosis by another medically
established diagnostic product or procedure.

References:

1. Vlassenbroeck I. et al. Validation of Real-Time Methylation-
Specific PCR to Determine O(6)-Methylguanine-DNA Methyltransferase
Gene Promoter Methylation in Glioma. J. Molecular Diagnostics
10;4:332-337. 2008

[page 4 of 4]
2. Hegi M. et al. MGMT Gene Silencing and Benefit from Temozolomide in Glioblastoma. New England J Medicine 352; 10:997-1003. 2005.
3. Brandes A. et al. MGMT Promoter Methylation Status Can Predict the Incidence and Outcome of Pseudoprogression After Concomitant Radiochemotherapy in Newly Diagnosed Glioblastoma Patients. J. Clinical Oncology 26; 13:2192-2197. 2008.
4. Hau P. et al. MGMT Methylation Status: The Advent of Stratified Therapy in Glioblastoma. Disease Markers 23:97-104. 2007.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

, M.D.

Performed by: SURGICAL PATHOLOGY
Electronically signed: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 52d3d7f3-cbca-4029-a52f-23ad8b82402f (TCGA-E1-A7Z6.096B03E5-82A9-41E6-BC6D-CA25D748EBDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).